Somatic mutation profile of tumor specimen TCGA-EE-A2A5-06A (aliquot TCGA-EE-A2A5-06A-11D-A197-08) from TCGA case TCGA-EE-A2A5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.4 years (16,942 days).
Specimen TCGA-EE-A2A5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20b76c5e-504f-4605-9974-08fb025f2b59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2A5-10A (Blood Derived Normal), aliquot TCGA-EE-A2A5-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fc7bdfc-b4d8-4577-b25a-d45601424004

The open-access MAF lists 390 somatic variants for this specimen: 260 protein-altering or splice-affecting, 121 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 230, Silent 121, Nonsense Mutation 21, Intron 6, Splice Region 4, Frame Shift Del 3, 3'Flank 1, 3'UTR 1, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAB21L2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777514, CM145907, COSV58261294; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 82/137 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV67100107; called by muse, mutect2, varscan2
- ACSS3 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV54100251, COSV54102464; called by muse, mutect2, varscan2
- AGFG2 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV53547355; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AIRE | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1245311654, COSV52397535; called by muse, mutect2, varscan2
- ALPK1 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368719469, COSV51592656; called by muse, mutect2, varscan2
- ALPK2 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV64497741; called by muse, mutect2, varscan2
- AMIGO2 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 28/30 reads (93%) | catalogued as COSV56975748; called by muse, mutect2, varscan2
- ANGPT1 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433491; called by muse, mutect2, varscan2
- ANGPTL5 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57534744; called by muse, mutect2, varscan2
- ARPP21 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV51809458; called by muse, mutect2, varscan2
- ASMTL | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67245299; called by muse, mutect2, varscan2
- ATAD2B | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV53206368; called by mutect2, varscan2
- ATF7IP2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs779112414, COSV61095610; called by muse, mutect2, varscan2
- ATP10D | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV56713774; called by muse, mutect2, varscan2
- ATP2B2 | c.2416G>A p.V806M (on ENST00000352432; = p.V772M on NM_001683.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421342790, COSV59508295; called by mutect2, varscan2
- ATP7B | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99667024; called by muse, mutect2, varscan2
- ATRNL1 | c.3655-1G>A p.X1219_splice | Splice Site (SNP) | VAF 21/28 reads (75%) | catalogued as COSV58117519; called by muse, mutect2, varscan2
- BAP1 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as COSV56241371; called by muse, varscan2
- BMP6 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.593); catalogued as COSV51672993; called by muse, mutect2, varscan2
- BPIFB4 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs267605884, COSV64952551; called by muse, mutect2, varscan2
- BRD7 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 66/85 reads (78%) | catalogued as COSV67158579; called by muse, mutect2, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- C11orf58 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV57179356; called by muse, mutect2, varscan2
- C20orf144 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768782763, COSV99865217; called by muse, mutect2, varscan2
- CA9 | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV65676641; called by muse, mutect2, varscan2
- CACNA1C | c.4025G>A p.R1342H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1365999989, COSV59762077, COSV59778286; called by muse, mutect2, varscan2
- CALCR | c.1318C>T p.R440C (on ENST00000649521 / NM_001164737.2; = p.R424C on NM_001742.4) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs753381450, COSV64005530; called by muse, mutect2, varscan2
- CAPZA3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs377290206, COSV56856804; called by muse, mutect2, varscan2
- CATIP | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200499642, COSV99179664; called by muse, mutect2, varscan2
- CAVIN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV58423225; called by muse, varscan2
- CBX4 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99490620; called by muse, mutect2, varscan2
- CCDC141 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs914187336, COSV55370770; called by muse, mutect2, varscan2
- CCDC158 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.23); catalogued as COSV66357318; called by muse, mutect2, varscan2
- CCDC39 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56494787; called by muse, mutect2, varscan2
- CCDC74A | c.948C>T p.P316= | Splice Region (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99723962; called by muse, mutect2, varscan2
- CD163 | c.2358G>A p.M786I | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63131154; called by muse, mutect2, varscan2
- CD34 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV60415463; called by muse, mutect2, varscan2
- CD8B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs767948136, COSV58928811; called by muse, mutect2, varscan2
- CDH10 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760208493, COSV52594806; called by muse, mutect2, varscan2
- CDH6 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54079330; called by muse, mutect2, varscan2
- CEP85L | c.2025C>T p.N675= | Splice Region (SNP) | VAF 49/59 reads (83%) | catalogued as COSV63829147; called by muse, mutect2, varscan2
- CFTR | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.158); catalogued as CM066751, COSV50113490; called by muse, mutect2, varscan2
- CHGB | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66761950; called by muse, mutect2, varscan2
- CLEC4M | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs138729831; called by muse, mutect2
- COL3A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58581957; called by muse, mutect2, varscan2
- COL4A2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 39/110 reads (35%) | catalogued as rs762951574, COSV64627172; called by muse, mutect2, varscan2
- COL6A5 | c.7496C>T p.P2499L (on ENST00000312481; = p.P2495L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55217730; called by muse, mutect2, varscan2
- COL9A2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs767307495, COSV65607354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA3 | c.1095G>A p.W365* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV56047698; called by muse, mutect2, varscan2
- CR1 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65464323; called by muse, varscan2
- CRB2 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63505890; called by muse, mutect2, varscan2
- CSF2RB | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as COSV53260136; called by muse, mutect2, varscan2
- DEFB121 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.887); catalogued as COSV66236286; called by muse, mutect2, varscan2
- DENND2C | c.1528C>T p.P510S (on ENST00000393274 / NM_001256404.2; = p.P453S on NM_198459.4) | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV67922765; called by muse, mutect2, varscan2
- DISP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53822416; called by muse, mutect2, varscan2
- DNER | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as rs866256730, COSV59163145; called by muse, mutect2, varscan2
- DSG1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs867148186, COSV57136042; called by muse, mutect2, varscan2
- DSG3 | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57130017, COSV57130094; called by muse, mutect2, varscan2
- EAF2 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV56546270; called by muse, mutect2, varscan2
- ECE1 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs757207956, COSV99942447; called by mutect2, varscan2
- EFCAB3 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV59505285; called by muse, mutect2, varscan2
- EIF3D | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV53405643; called by muse, mutect2, varscan2
- EML5 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1002132947, COSV61352314; called by muse, mutect2, varscan2
- EPHA3 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60729666; called by muse, mutect2, varscan2
- EPHA6 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV67581723; called by muse, mutect2, varscan2
- FAM83B | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as rs1440039087, COSV60919763; called by muse, mutect2, varscan2
- FAT1 | c.8050G>A p.E2684K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV71672478, COSV71676217; called by muse, mutect2, varscan2
- FAT2 | c.6821A>G p.Q2274R | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV55830821; called by muse, mutect2, varscan2
- FATE1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.722); catalogued as COSV64848910, COSV64849232; called by muse, mutect2, varscan2
- FBN3 | c.3503T>G p.V1168G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54474461; called by muse, mutect2, varscan2
- FGF16 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV71546198; called by muse, mutect2, varscan2
- FLRT3 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.161); catalogued as COSV54062171; called by muse, mutect2, varscan2
- FLT3 | c.391T>G p.L131V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54072872; called by muse, mutect2, varscan2
- FNDC3B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.229); catalogued as COSV61050729; called by muse, mutect2, varscan2
- FREM1 | c.5723G>A p.G1908E | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV66531047; called by muse, mutect2, varscan2
- FYB2 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as rs866866257, COSV58585657; called by muse, mutect2, varscan2
- GALNT13 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV67241076; called by muse, mutect2, varscan2
- GALNT14 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.313); catalogued as rs1048696828, COSV61111062; called by muse, mutect2, varscan2
- GALNT17 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV61194688; called by muse, mutect2, varscan2
- GNA14 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV100503436; called by muse, mutect2, varscan2
- GNE | c.1600C>T p.P534S (on ENST00000396594 / NM_001128227.3; = p.P503S on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV64953277; called by muse, mutect2, varscan2
- GPC5 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV65621934; called by muse, mutect2, varscan2
- GPR174 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs764297256, COSV52133391; called by muse, mutect2, varscan2
- GPR50 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV54443383; called by muse, mutect2, varscan2
- GRB14 | c.313A>T p.R105W | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV55744088; called by muse, mutect2, varscan2
- GRIN2C | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53118436; called by mutect2, varscan2
- GRM5 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1168384385, COSV59632479; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2252C>T p.P751L (on ENST00000265755 / NM_016328.3; = p.P736L on NM_005685.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs1554358186, COSV99735723; called by muse, mutect2, varscan2
- H2AC13 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100704452; called by muse, varscan2
- HPD | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV56643933; called by muse, mutect2, varscan2
- HPF1 | c.605C>A p.S202* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV66422945; called by muse, mutect2, varscan2
- HUNK | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.12); catalogued as rs532775196, COSV54235037; called by muse, varscan2
- IGKV3-11 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.996); catalogued as rs561081030; called by muse, mutect2, varscan2
- IGSF21 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV52143819; called by muse, mutect2, varscan2
- IGSF9 | c.3194G>A p.W1065* (on ENST00000368094 / NM_001135050.2; = p.W1049* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 44/72 reads (61%) | catalogued as COSV57421921, COSV57423891; called by muse, mutect2, varscan2
- IL10RB | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV51617494; called by muse, varscan2
- IL36B | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.389); catalogued as COSV52088962; called by muse, mutect2, varscan2
- INVS | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV52450992; called by muse, mutect2, varscan2
- IQGAP2 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as rs534842328, COSV57169035; called by muse, mutect2, varscan2
- ITGB3 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV71385300; called by muse, mutect2, varscan2
- JHY | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57080876; called by muse, mutect2, varscan2
- KCNA1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838908, COSV99059679; called by muse, mutect2, varscan2
- KCNC4 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV100873702; called by muse, mutect2
- KCNC4 | c.1586A>C p.E529A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100873703; called by muse, mutect2
- KCNK2 | c.350T>G p.L117R (on ENST00000444842 / NM_001017425.3; = p.L102R on NM_014217.4) | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101222369, COSV67204595; called by muse, mutect2, varscan2
- KCNMA1 | c.3104G>A p.G1035E (on ENST00000286628 / NM_001161352.2; = p.G977E on NM_002247.4) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99700156; called by muse, mutect2, varscan2
- KCNMA1 | c.3103G>A p.G1035R (on ENST00000286628 / NM_001161352.2; = p.G977R on NM_002247.4) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698685, COSV99700165; called by muse, mutect2, varscan2
- KCNQ3 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.224); catalogued as COSV66483192; called by muse, mutect2, varscan2
- KCNT1 | c.3089C>T p.S1030F (on ENST00000488444; = p.S1049F on NM_020822.3) | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99706879; called by muse, mutect2, varscan2
- KCTD8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63593710; called by muse, mutect2, varscan2
- KIF16B | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs779575204, COSV100734216; called by muse, mutect2, varscan2
- KIF3B | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV65229558; called by muse, mutect2, varscan2
- KLHL11 | c.1930C>T p.L644F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59861436; called by muse, mutect2, varscan2
- KRT222 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67499385; called by muse, mutect2, varscan2
- KRTAP10-7 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1555928846, COSV59113617; called by muse, mutect2, varscan2
- KSR2 | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56666308; called by muse, mutect2, varscan2
- KYAT3 | c.1016T>G p.F339C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53106060; called by muse, mutect2, varscan2
- LAMA1 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67545093; called by muse, mutect2, varscan2
- LCT | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51558480; called by muse, mutect2, varscan2
- LIMCH1 | c.2277G>A p.M759I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1272450559, COSV58298508; called by muse, mutect2, varscan2
- LRGUK | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53644693; called by muse, mutect2, varscan2
- LRRC42 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV59962087; called by muse, mutect2, varscan2
- LRRIQ4 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV61619225; called by muse, mutect2, varscan2
- MACIR | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100174818; called by muse, mutect2, varscan2
- MACIR | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.05); catalogued as rs782715851, COSV100174820; called by muse, mutect2, varscan2
- MACIR | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV60636288; called by muse, mutect2, varscan2
- MAGEC2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1421719984, COSV56000704; called by muse, mutect2, varscan2
- MAST4 | c.1286C>T p.S429F (on ENST00000403625 / NM_001164664.2; = p.S240F on NM_015183.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55138991; called by muse, mutect2, varscan2
- MECOM | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV72110006; called by muse, mutect2, varscan2
- MGA | c.8153T>C p.V2718A (on ENST00000219905 / NM_001164273.1; = p.V2509A on NM_001080541.2) | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV54964198; called by muse, mutect2, varscan2
- MGAM | c.1114C>T p.L372F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV72075998; called by muse, mutect2
- MORC1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV51732628; called by muse, mutect2, varscan2
- MTOR | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV63879016; called by muse, mutect2, varscan2
- MUC16 | c.27357G>A p.M9119I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as COSV67497871; called by muse, mutect2, varscan2
- MUC16 | c.6799C>T p.P2267S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67456280; called by muse, mutect2
- MYCBP2 | c.9350C>T p.P3117L (on ENST00000357337; = p.P3155L on NM_015057.5) | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV62041539; called by muse, mutect2, varscan2
- MYH3 | c.3533A>G p.D1178G | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56870666; called by muse, varscan2
- MYO16 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.166); catalogued as COSV51821069; called by muse, mutect2, varscan2
- MYO18B | c.6721G>A p.E2241K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59142369; called by muse, mutect2, varscan2
- MYO3A | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs56403976, COSV56324596; called by muse, mutect2, varscan2
- MYOCD | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58506546; called by muse, mutect2, varscan2
- N6AMT1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58136034; called by muse, mutect2, varscan2
- NCKAP5L | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV60134515; called by muse, mutect2, varscan2
- NDST4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); catalogued as COSV52139504; called by muse, mutect2, varscan2
- NDUFB2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776657486, COSV52596306; called by muse, mutect2, varscan2
- NOTCH2 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 324/566 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs782306821, COSV56700266; called by muse, mutect2, varscan2
- NRG1 | c.1537C>T p.P513S (on ENST00000405005 / NM_013964.5; = p.P518S on NM_013956.5) | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55177470; called by muse, mutect2, varscan2
- NRK | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54604671, COSV54608111; called by muse, mutect2, varscan2
- NTN4 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766077128, COSV59223700; called by muse, mutect2, varscan2
- NYAP2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs780236043, COSV56017452; called by muse, mutect2, varscan2
- OCIAD1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.43); catalogued as COSV51903162; called by muse, mutect2, varscan2
- OPHN1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV62787536; called by muse, mutect2, varscan2
- OR13C2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV73377811; called by muse, mutect2, varscan2
- OR1F1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58962660; called by muse, mutect2, varscan2
- OR2G6 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV104413553, COSV58575998; called by muse, mutect2, varscan2
- OR4Q3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs867709774, COSV59177540, COSV59179709; called by muse, mutect2, varscan2
- OR5AR1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 84/102 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200490684, COSV57253053; called by muse, varscan2
- OR6B1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV68770684; called by muse, mutect2, varscan2
- OR7A5 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.26); catalogued as COSV59235739; called by muse, mutect2, varscan2
- OVGP1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63860205; called by muse, mutect2, varscan2
- PASD1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64857665; called by muse, mutect2, varscan2
- PCARE | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1192027916, COSV59058572; called by muse, mutect2, varscan2
- PCDHGA2 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs776431934, COSV53946657; called by muse, mutect2, varscan2
- PCDHGA3 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV53908106; called by muse, mutect2, varscan2
- PDE11A | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.531); catalogued as COSV53685657; called by muse, mutect2, varscan2
- PER1 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57922289; called by muse, mutect2, varscan2
- PHF21B | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs370911252, COSV57562876; called by muse, mutect2, varscan2
- PLCH1 | c.4876G>A p.V1626M (on ENST00000340059 / NM_001130960.2; = p.V1618M on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.44); catalogued as rs1353097739, COSV58211114; called by muse, mutect2, varscan2
- PLD2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV54010442; called by muse, mutect2, varscan2
- PLEKHH2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 118/355 reads (33%) | catalogued as rs866990001, COSV56761913; called by muse, mutect2, varscan2
- PLG | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as rs961449882, COSV99804519; called by muse, mutect2, varscan2
- POMGNT2 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100768168, COSV60954969; called by muse, mutect2, varscan2
- POMGNT2 | c.778T>G p.S260A | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV100768170; called by muse, mutect2, varscan2
- POTED | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55048602; called by muse, mutect2, varscan2
- POTEE | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58246280; called by muse, mutect2, varscan2
- POU4F2 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs780725416, COSV55587064; called by muse, mutect2, varscan2
- PPARD | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.123); catalogued as rs771421269, COSV61101675; called by muse, varscan2
- PRC1 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 310/383 reads (81%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1002708250, COSV62696801; called by muse, mutect2, varscan2
- PRELID2 | c.356C>T p.S119F (on ENST00000334744 / NM_182960.4; = p.S78F on NM_138492.6) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1293877325, COSV58282220; called by muse, mutect2, varscan2
- PRKAG3 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746230559, COSV52103948; called by muse, mutect2, varscan2
- PRKD3 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52219399; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 144/289 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTK2B | c.2598C>T p.S866= | Splice Region (SNP) | VAF 19/26 reads (73%) | catalogued as COSV57767423; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- RBL1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328281715, COSV60334255; called by muse, mutect2, varscan2
- RBM15B | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as COSV60047062; called by muse, mutect2, varscan2
- RFX5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755766544, COSV51841948; called by muse, mutect2, varscan2
- RHPN1 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100000939; called by muse, mutect2, varscan2
- RIF1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs192238663, COSV54625215; called by muse, mutect2, varscan2
- RNF220 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV62410220; called by muse, mutect2, varscan2
- RTL4 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 43/52 reads (83%) | catalogued as COSV61207422; called by muse, mutect2, varscan2
- SALL1 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51765167; called by muse, mutect2, varscan2
- SALL3 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs180936492, COSV73306651; called by muse, mutect2, varscan2
- SAMD9 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV66077873; called by muse, mutect2, varscan2
- SCAP | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768447765, COSV55560369; called by muse, mutect2, varscan2
- SCGN | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200726171; called by muse, mutect2, varscan2
- SCN1A | c.3139G>A p.E1047K (on ENST00000303395 / NM_001202435.3; = p.E1036K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs776984527, CM113312, COSV57664062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETBP1 | c.1945C>T p.H649Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs1168255441, COSV56338457; called by muse, mutect2, varscan2
- SGSM1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV68514106; called by muse, mutect2, varscan2
- SIGLEC8 | c.371T>A p.F124Y | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV58476107; called by muse, mutect2, varscan2
- SLAMF1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.694); catalogued as COSV52502553; called by muse, mutect2, varscan2
- SLC27A6 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52483149; called by muse, mutect2, varscan2
- SLC4A4 | c.2036G>A p.G679E (on ENST00000264485 / NM_001098484.3; = p.G635E on NM_003759.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52621253, COSV52627637; called by muse, mutect2, varscan2
- SLC6A18 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99722725; called by muse, mutect2, varscan2
- SLC6A18 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as COSV57254806; called by mutect2, varscan2
- SMPD3 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as rs1166862303, COSV54716622; called by muse, varscan2
- SNED1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV60034411; called by muse, mutect2, varscan2
- SPAG16 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55985864; called by muse, mutect2, varscan2
- ST3GAL5 | c.1064C>A p.T355N (on ENST00000377332; = p.T395N on NM_003896.4) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752098198, COSV66152267; called by muse, mutect2, varscan2
- ST6GAL2 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV62418310; called by muse, mutect2, varscan2
- STAB1 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58743805; called by muse, mutect2, varscan2
- STAB2 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66341932; called by muse, mutect2, varscan2
- STK38L | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | catalogued as rs1372876016, COSV66521473; called by muse, mutect2, varscan2
- SUCLG1 | c.293T>C p.L98S | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as COSV67266042; called by muse, mutect2, varscan2
- SVEP1 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57049186; called by muse, mutect2, varscan2
- TAF1L | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as rs761429692, COSV54258619; called by muse, mutect2, varscan2
- TBC1D10A | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53166219; called by muse, mutect2, varscan2
- TBL1XR1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV101467821, COSV70499453; called by muse, mutect2, varscan2
- TBL1XR1 | c.1071G>A p.W357* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101467806, COSV70501824; called by muse, mutect2, varscan2
- TBX20 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68786136; called by muse, mutect2, varscan2
- TCP11 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs909615555, COSV55136381; called by muse, mutect2, varscan2
- TDRD7 | c.2159G>C p.R720P | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100795432, COSV62430982, COSV62431215; called by muse, mutect2, varscan2
- TECTA | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 44/57 reads (77%) | catalogued as COSV50819185; called by muse, mutect2, varscan2
- TENM2 | c.4912A>T p.I1638F (on ENST00000518659 / NM_001122679.2; = p.I1399F on NM_001080428.3) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV69143343; called by muse, mutect2, varscan2
- TG | c.7534C>T p.Q2512* | Nonsense Mutation (SNP) | VAF 131/257 reads (51%) | catalogued as COSV55096418; called by muse, mutect2, varscan2
- THYN1 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as rs1280441446, COSV55542982; called by muse, mutect2, varscan2
- TLR4 | c.2474G>A p.G825E (on ENST00000355622 / NM_138554.5; = p.G785E on NM_003266.4) | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.266); catalogued as COSV62922445; called by muse, mutect2, varscan2
- TMEM132B | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.816); catalogued as COSV100171163, COSV54748471; called by muse, mutect2, varscan2
- TMEM74B | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV67892382; called by muse, mutect2, varscan2
- TNN | c.3784G>A p.G1262R | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53436224; called by muse, mutect2, varscan2
- TRANK1 | c.6877T>A p.F2293I | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV57147836, COSV57148300; called by muse, mutect2, varscan2
- TRANK1 | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763592869, COSV57165830; called by mutect2, varscan2
- TRAPPC9 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs35318201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM15 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.419); catalogued as COSV64990533; called by muse, mutect2, varscan2
- TRPC6 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV60261710; called by muse, mutect2, varscan2
- TTN | c.26308G>A p.G8770R (on ENST00000591111; = p.G7843R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | PolyPhen probably damaging (0.992); catalogued as COSV60383248; called by muse, mutect2, varscan2
- TTN | c.22436G>A p.R7479Q (on ENST00000591111; = p.R6552Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | PolyPhen benign (0.293); catalogued as rs267599059; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6217C>T p.P2073S (on ENST00000591111; = p.P2027S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | PolyPhen possibly damaging (0.859); catalogued as COSV60060075; called by muse, mutect2, varscan2
- TUBGCP6 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs968790589, COSV50592946; called by muse, mutect2, varscan2
- UGT2B7 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV59445760; called by muse, mutect2, varscan2
- USP34 | c.10238A>T p.K3413I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV63725916; called by muse, mutect2, varscan2
- XRN1 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV53818900; called by muse, mutect2, varscan2
- YTHDF2 | c.101T>A p.F34Y | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV65724250; called by mutect2, varscan2
- ZAN | c.4084C>T p.H1362Y | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.134); catalogued as rs776205874, COSV61817688; called by muse, mutect2, varscan2
- ZCCHC2 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs527473058, COSV54041553; called by muse, mutect2, varscan2
- ZFP42 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100478558, COSV58819515; called by muse, varscan2
- ZNF181 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67627339; called by muse, mutect2, varscan2
- ZNF417 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs1170177267, COSV56310236; called by muse, mutect2, varscan2
- ZNF521 | c.243T>A p.D81E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as COSV100833559; called by muse, mutect2, varscan2
- ZNF564 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1390256577, COSV59436809; called by muse, mutect2, varscan2
- ZSWIM2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54580846; called by muse, mutect2, varscan2
- DAZAP1 | c.658_663del p.G220_Q221del | In Frame Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, varscan2
- FBXL18 | c.1234_1235del p.L412Afs*15 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- LAMP3 | c.708_709del p.C237Yfs*61 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by pindel, varscan2
- PLEKHO1 | c.222_229del p.D74Efs*3 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2*, pindel, varscan2*
- PRKCQ | c.1380_1406delinsAGTCCC p.Y460_H469delins* | Nonsense Mutation (DEL) | VAF 41/69 reads (59%) | called by pindel, varscan2*
- SPATA31A1 | c.953T>A p.F318Y | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ABCA3 | c.864G>A p.R288= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57060746; called by muse, varscan2
- ABCB4 | c.1971C>T p.G657= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV55942498; called by muse, mutect2, varscan2
- ACSM2A | c.1575G>A p.K525= (on ENST00000219054; = p.K446= on NM_001308169.2) | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as COSV54583715, COSV54590497; called by muse, mutect2, varscan2
- ADCY10 | c.1476G>A p.E492= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV63242138, COSV63245479; called by muse, mutect2, varscan2
- ALG8 | c.306C>T p.T102= | Silent (SNP) | VAF 41/50 reads (82%) | catalogued as COSV55203383; called by muse, mutect2, varscan2
- ANKS1B | c.1572C>T p.P524= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV61379163; called by muse, mutect2, varscan2
- ANO10 | c.948G>A p.L316= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99429154; called by muse, mutect2, varscan2
- ASB4 | c.150C>T p.V50= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs553585471, COSV57508451; called by muse, mutect2, varscan2
- ATP2B2 | c.837C>T p.N279= | Silent (SNP) | VAF 66/125 reads (53%) | catalogued as rs773005890, COSV59508304; called by muse, varscan2
- ATP7B | c.1392G>A p.G464= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as rs1287996513, COSV54435262, COSV99666064; called by muse, mutect2, varscan2
- BCO2 | c.315G>A p.G105= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as COSV63065179; called by muse, mutect2, varscan2
- BMP6 | c.1173C>T p.S391= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs751622797, COSV51673002; called by muse, mutect2, varscan2
- BSN | c.1977G>A p.G659= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV56528965; called by muse, mutect2, varscan2
- C20orf144 | c.153G>A p.L51= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99865213; called by muse, mutect2, varscan2
- CBX4 | c.214A>C p.R72= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99490622; called by muse, mutect2, varscan2
- CDH6 | c.984T>C p.I328= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54079321; called by muse, mutect2, varscan2
- CENPF | c.5286C>T p.F1762= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV65279545; called by muse, mutect2, varscan2
- CHRM3 | c.303G>A p.T101= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs200122635, COSV55100476, COSV55106765; called by muse, mutect2, varscan2
- CR2 | c.2784G>A p.R928= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs762689637, COSV65509977; called by muse, mutect2, varscan2
- CYP2C9 | c.126C>T p.I42= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as rs926601822, COSV53253415; called by muse, mutect2, varscan2
- DAB1 | c.93G>A p.L31= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs755664004, COSV59738487; called by muse, mutect2, varscan2
- DCC | c.1479G>A p.K493= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs772474178, COSV59097617, COSV59139949; called by muse, varscan2
- DCDC1 | c.2331G>A p.E777= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV60860615; called by muse, mutect2, varscan2
- DEFA3 | c.183G>A p.R61= | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as rs1236091086, COSV59935544; called by muse, mutect2, varscan2
- DLEC1 | c.3081C>T p.G1027= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV57307505; called by muse, mutect2, varscan2
- DNAH7 | c.8826C>T p.I2942= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV56758162, COSV56781474; called by muse, mutect2, varscan2
- EEF2K | c.144G>A p.S48= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs529625938, COSV53787712; called by muse, mutect2, varscan2
- EPS15L1 | c.1455A>G p.Q485= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs568168176, COSV50176608; called by muse, mutect2, varscan2
- FABP6 | c.192C>T p.F64= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1424019758, COSV67437816; called by muse, mutect2, varscan2
- FAM83F | c.1329C>T p.F443= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV61001715; called by muse, mutect2, varscan2
- FN1 | c.3468G>A p.L1156= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV60565348; called by muse, mutect2, varscan2
- GABRP | c.1203G>A p.R401= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54666030; called by muse, mutect2, varscan2
- GHRHR | c.124C>T p.L42= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100396816, COSV58198449; called by muse, mutect2, varscan2
- GINS4 | c.78C>T p.L26= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV52532291; called by muse, varscan2
- GLB1L3 | c.372G>A p.P124= | Silent (SNP) | VAF 82/108 reads (76%) | catalogued as rs199664947, COSV66281805; called by muse, mutect2, varscan2
- GNA14 | c.915C>T p.I305= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs775748876, COSV100503440; called by muse, mutect2, varscan2
- GOLGB1 | c.2673C>T p.T891= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV100511625; called by muse, mutect2, varscan2
- GRID2 | c.741G>A p.V247= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs762100538, COSV56274646; called by muse, varscan2
- GRIK3 | c.126C>T p.F42= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs779625285, COSV66147770, COSV66149017; called by muse, mutect2, varscan2
- HEXD | c.1419G>A p.L473= (on ENST00000327949 / NM_001369487.1; = p.C503Y on NM_173620.3) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1157862688, COSV60066345; called by mutect2, varscan2
- HMGXB4 | c.1083C>T p.G361= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV53336188; called by muse, mutect2, varscan2
- IARS1 | c.489C>T p.F163= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV65117349; called by muse, mutect2, varscan2
- IGSF3 | c.3312C>T p.I1104= (on ENST00000369486 / NM_001007237.3; = p.I1124= on NM_001542.4) | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as rs769333106, COSV59599336; called by muse, mutect2, varscan2
- IL10RB | c.654C>T p.V218= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as COSV99270205; called by muse, varscan2
- IL1RL2 | c.1362C>T p.P454= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs556319990, COSV51816031; called by muse, mutect2, varscan2
- KANK2 | c.2115T>C p.I705= (on ENST00000586659 / NM_001379562.1; = p.I713= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV62010350; called by muse, mutect2, varscan2
- KCNC3 | c.1356C>T p.I452= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs147215054; called by muse, mutect2, varscan2
- KCNK2 | c.351C>A p.L117= (on ENST00000444842 / NM_001017425.3; = p.L102= on NM_014217.4) | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as COSV101222373; called by muse, mutect2, varscan2
- KCNT1 | c.3090C>T p.S1030= (on ENST00000488444; = p.S1049= on NM_020822.3) | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as rs765432746, COSV99706884; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIF16B | c.396G>A p.R132= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100734992; called by muse, mutect2, varscan2
- KIR2DL1 | c.699A>G p.E233= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as rs1471483095, COSV52409320; called by muse, mutect2, varscan2
- LAMB3 | c.2553G>A p.Q851= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV61920171; called by muse, mutect2, varscan2
- LINGO4 | c.1338C>T p.S446= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100765055; called by muse, mutect2, varscan2
- LMF1 | c.1344C>T p.P448= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs760744893, COSV51903168; called by muse, mutect2, varscan2
- LMTK2 | c.3739C>T p.L1247= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52004068; called by muse, mutect2, varscan2
- LRFN1 | c.303C>T p.I101= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV50510453; called by mutect2, varscan2
- LRFN2 | c.2169C>T p.S723= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs755125063, COSV57835338; called by muse, mutect2, varscan2
- MAGEE2 | c.1557C>T p.F519= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as COSV64898611; called by muse, mutect2, varscan2
- MAIP1 | c.630C>T p.S210= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV54461701; called by muse, mutect2, varscan2
- MAP1S | c.123C>T p.I41= | Silent (SNP) | VAF 52/83 reads (63%) | catalogued as rs149771755, COSV60724847; called by muse, mutect2, varscan2
- MAST4 | c.1287C>T p.S429= (on ENST00000403625 / NM_001164664.2; = p.S240= on NM_015183.3) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99846197; called by muse, mutect2, varscan2
- MED15 | c.1503C>T p.F501= (on ENST00000263205 / NM_001003891.3; = p.F461= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV53034051; called by muse, mutect2, varscan2
- MEGF6 | c.1458G>A p.Q486= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs749549712, COSV53896473; called by muse, mutect2
- MPP2 | c.366C>T p.P122= (on ENST00000461854 / NM_001278372.2; = p.P98= on NM_005374.5) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99290903; called by muse, mutect2, varscan2
- MRGPRX1 | c.903G>A p.V301= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs772396259, COSV57109976; called by muse, mutect2, varscan2
- MYBBP1A | c.3309G>A p.L1103= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV54605149; called by muse, mutect2, varscan2
- MYH1 | c.3372G>A p.E1124= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as COSV56858150; called by muse, mutect2, varscan2
- MYO1D | c.2553G>A p.K851= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs899836006, COSV59024731; called by muse, mutect2, varscan2
- NMUR2 | c.1062C>T p.D354= | Silent (SNP) | VAF 67/103 reads (65%) | catalogued as COSV54923245; called by muse, mutect2, varscan2
- NYNRIN | c.4077C>T p.A1359= | Silent (SNP) | VAF 42/54 reads (78%) | catalogued as rs939969864, COSV66845429; called by muse, mutect2, varscan2
- OR10J3 | c.39C>T p.L13= | Silent (SNP) | VAF 111/177 reads (63%) | catalogued as COSV59955028; called by muse, mutect2, varscan2
- OR4D10 | c.498C>T p.L166= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV73260220; called by muse, mutect2, varscan2
- OR4M1 | c.279C>T p.S93= | Silent (SNP) | VAF 100/252 reads (40%) | catalogued as COSV60062196, COSV60063846; called by muse, mutect2, varscan2
- OR52E4 | c.180C>T p.P60= | Silent (SNP) | VAF 60/72 reads (83%) | catalogued as rs1002744926, COSV57625303; called by muse, mutect2, varscan2
- OR5V1 | c.633C>T p.F211= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV65826333; called by muse, mutect2, varscan2
- OR6Y1 | c.60G>A p.L20= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV56931565; called by muse, mutect2, varscan2
- PCNX1 | c.4560C>T p.F1520= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs369367255; called by muse, mutect2, varscan2
- PKHD1L1 | c.900C>T p.F300= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs766490485, COSV65736524; called by muse, mutect2, varscan2
- PLG | c.1074C>T p.S358= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV99805196; called by muse, mutect2, varscan2
- POC1A | c.1075C>T p.L359= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV99624669; called by muse, mutect2, varscan2
- POC1A | c.1074A>T p.T358= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV99624672; called by muse, mutect2, varscan2
- PPP1R1C | c.207G>A p.R69= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV54720073; called by muse, mutect2, varscan2
- PRAMEF6 | c.408G>A p.Q136= | Silent (SNP) | VAF 127/214 reads (59%) | catalogued as rs747480899, COSV61910610; called by muse, mutect2, varscan2
- PSD2 | c.1035G>A p.L345= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs1430359283, COSV51213975; called by muse, mutect2, varscan2
- PTPRT | c.2949C>T p.I983= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs1032558148, COSV61981979; called by muse, mutect2, varscan2
- RAB40AL | c.771G>A p.V257= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV54435995; called by muse, mutect2, varscan2
- RASEF | c.1137G>A p.G379= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV64588938; called by muse, mutect2, varscan2
- RASSF6 | c.1062G>A p.L354= (on ENST00000342081 / NM_201431.2; = p.L322= on NM_177532.5) | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1359643863, COSV56721527; called by muse, mutect2, varscan2
- RELB | c.420C>T p.F140= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV55513265; called by muse, mutect2, varscan2
- RHPN1 | c.1599C>T p.V533= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100000937; called by muse, mutect2, varscan2
- SASH1 | c.2850C>T p.G950= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV66566540; called by muse, mutect2, varscan2
- SCN1A | c.2898C>T p.A966= (on ENST00000303395 / NM_001202435.3; = p.A955= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs774054004, COSV57690086; called by muse, mutect2, varscan2
- SHCBP1L | c.1092C>T p.F364= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV62357485; called by muse, mutect2, varscan2
- SLC33A1 | c.159G>A p.L53= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV63947808; called by muse, mutect2, varscan2
- SLC34A2 | c.555C>T p.I185= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV65943310; called by muse, mutect2, varscan2
- SLCO5A1 | c.879C>T p.V293= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as COSV52669270; called by muse, mutect2, varscan2
- SMARCC2 | c.741C>T p.T247= | Silent (SNP) | VAF 57/69 reads (83%) | catalogued as COSV57225633; called by muse, mutect2, varscan2
- SOHLH2 | c.63C>T p.I21= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs199652715, COSV58523690; called by muse, mutect2, varscan2
- SRCAP | c.7617A>G p.S2539= | Silent (SNP) | VAF 64/181 reads (35%) | catalogued as COSV52682034; called by muse, mutect2, varscan2
- TAS2R60 | c.231C>T p.T77= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs185837132; called by muse, mutect2, varscan2
- TMPRSS11B | c.297C>T p.V99= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV60294367; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2919G>A p.Q973= | Silent (SNP) | VAF 61/74 reads (82%) | catalogued as rs1347371745, COSV64102848; called by muse, mutect2, varscan2
- TNS3 | c.573C>T p.F191= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs368113552; called by mutect2, varscan2
- TRANK1 | c.8274G>A p.R2758= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV57165802; called by muse, mutect2, varscan2
- TRIM54 | c.114G>A p.V38= | Silent (SNP) | VAF 82/170 reads (48%) | catalogued as COSV56081437; called by muse, mutect2, varscan2
- TRIO | c.7554C>T p.A2518= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV59992656; called by muse, mutect2, varscan2
- TRPM2 | c.924C>T p.F308= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55978021; called by muse, mutect2, varscan2
- TTN | c.5412C>T p.S1804= (on ENST00000591111; = p.S1758= on NM_003319.4) | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV60383308; called by muse, mutect2, varscan2
- UBD | c.126G>A p.K42= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV63544780; called by muse, mutect2, varscan2
- UBE2E2 | c.6C>T p.S2= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1200835177, COSV59980087; called by muse, mutect2, varscan2
- UMODL1 | c.3612C>T p.S1204= (on ENST00000408910 / NM_001004416.2; = p.S1332= on NM_173568.3) | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV68571236; called by muse, mutect2, varscan2
- UNC93A | c.261C>T p.F87= | Silent (SNP) | VAF 67/84 reads (80%) | catalogued as rs773758433, COSV57810201; called by muse, mutect2, varscan2
- USP24 | c.6954G>A p.G2318= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV53775018, COSV53779864; called by muse, mutect2, varscan2
- WEE2 | c.951G>A p.K317= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV66880319; called by muse, mutect2, varscan2
- ZBED4 | c.2325G>A p.V775= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1388680661, COSV53468497; called by muse, mutect2, varscan2
- ZNF285 | c.1239C>T p.S413= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs566967165, COSV58408563, COSV58410133; called by muse, mutect2, varscan2
- ZNF331 | c.24C>T p.F8= | Silent (SNP) | VAF 159/306 reads (52%) | catalogued as rs745754895, COSV53480562; called by muse, mutect2, varscan2
- ZNF407 | c.6156C>G p.A2052= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100227366, COSV55255640; called by muse, mutect2, varscan2
- ZNF628 | c.471C>T p.F157= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV52702701, COSV99220390; called by mutect2, varscan2
- ZNF70 | c.651C>T p.I217= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV59533102; called by muse, mutect2, varscan2
- ZSWIM2 | c.1419C>T p.I473= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1453565875, COSV54580222; called by muse, mutect2, varscan2
- AGBL4 | c.1267+28G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+27G>A | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs761834505; called by muse, varscan2
- CSMD3 | c.*2G>A | 3'UTR (SNP) | VAF 75/208 reads (36%) | catalogued as rs1239977200, COSV99849983; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055798 A>T | 3'Flank (SNP) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- HMGB1P1 | n.237C>T | RNA (SNP) | VAF 71/147 reads (48%) | catalogued as rs1403542744; called by muse, mutect2, varscan2
- MASP1 | c.1303+4993C>T | Intron (SNP) | VAF 45/122 reads (37%) | catalogued as COSV99962931; called by muse, mutect2, varscan2
- MGAM | c.4618+5545G>A | Intron (SNP) | VAF 17/38 reads (45%) | catalogued as rs762786105, COSV101527782; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3051C>T | Intron (SNP) | VAF 44/60 reads (73%) | catalogued as COSV100315059; called by muse, mutect2, varscan2
- TTN | c.34265-4186C>T | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as rs755562550, COSV100633400; ClinVar: uncertain significance; called by mutect2, varscan2
